Gene-level copy-number profile of tumor specimen TCGA-CR-6487-01A from TCGA case TCGA-CR-6487, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tonsil, NOS; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 50.2 years (18,331 days).
Specimen TCGA-CR-6487-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.eeac45c2-92cc-42ca-b745-d06ed887e749.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CR-6487-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/fd9df84a-bb39-4e84-8cea-970966744f9d

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 8,844; copy number 2: 42,230; copy number 3: 7,573; copy number 4: 157; copy number 5: 359; copy number 8: 3; copy number 11: 2; copy number 13: 458; copy number 18: 194.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CR-6487-01A-11D-1869-01): tumor purity 0.39, ploidy 2.06, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,016 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:161,083,883–198,222,513, 657 genes, copy number 8–18 (broad region; genes not listed).
- chr9:10,631,750–34,691,276, 357 genes, copy number 5 (broad region; genes not listed).
- chr9:34,709,005–34,729,488, 2 genes, copy number 5 (within-gene range 2–5): CCL21, FAM205A.

Autosomal genes at a single copy (total copy number 1): 7,354. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
